Surgical pathology report (de-identified scan), TCGA case TCGA-RD-A7BS, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Peter MacCallum Cancer Center, specimen TCGA-RD-A7BS-01A (Primary Tumor).

[page 1 of 2]
DOB:
Male

Specimen No.

Collect Time:

Collect Date:

HISTOPATHOLOGY

Lab No:

MACROSCOPIC DESCRIPTION:

1. "Unlabelled as to site": The specimen is a section of distal oesophagus and proximal stomach measuring 100mm in length, 40mm in circumference at the oesophageal margin and 60mm in circumference at the gastric margin. There is attached mesentery and fat measuring up to 30mm in width. Located 40mm from the proximal (oesophageal) resection margin is a tumour mass arising at the gastro-oesophageal junction. The mucosal surface of the tumour is ulcerated and fungating. The tumour measures 20x20mm and extends to a depth of 12mm. The tumour appears to focally extend through the wall of the oesophagus into surrounding fat. The remainder of the stomach and oesophageal mucosa appears unremarkable.

BLOCK DESIGNATION:

- A - gastric resection margin
- B - oesophageal resection margin
- C & D - composite blocks through tumour
- E & F - further composite blocks through tumour
- G & H - lymph nodes

*ICD-O-3
Adenocarcinoma, diffuse type
Site Gastroesophageal junction
8/45/13
C/6 D
JW 9/25/13*

2. "High paraesophageal lymph node": A single fragment of tan coloured tissue measuring 5mm in maximum dimension. Submitted whole in one cassette.

3. "Low paraesophageal lymph node": An encapsulated lymph node measuring 7mm in maximum dimension. Submitted whole in one cassette.

MICROSCOPIC DESCRIPTION:

The sections show a poorly differentiated infiltrating adenocarcinoma arising at the gastro oesophageal junction from gastric cardia type mucosa. The surface of the tumour is ulcerated with islands of malignant glands seen infiltrating through the underlying muscularis propria and infiltrating deeply into surrounding serosal tissues. The individual tumour cells show a marked degree of nuclear and cytoplasmic pleomorphism with frequent mitotic figures and numerous signet cells also identified. Numerous pools of mucin are also identified within the tumour. Tumour extends to the painted posterior free serosal surface. No vascular or lymphatic invasion is identified. The oesophageal and gastric resection margins are clear of tumour and no evidence of gastritis is seen. H.pylori are not identified. Metastatic tumour is identified in three of six lymph nodes. Two of these show

Please contact the authorising Pathologist if you wish to discuss this case.

For enquiries on this report please contact
AUTHORISED BY

FINAL - File Permanently

This is a COPY

Printed:
Page 1 of 2

[page 2 of 2]
DOB:
Male

Specimen No.

Collect Time:

Collect Date:

extra nodal spread of tumour.

2. The sections show a lymph node with infiltration by metastatic tumour.

3. Sections show a lymph node with infiltration by metastatic tumour.

DIAGNOSIS:

1. Oesophago gastrectomy: Poorly differentiated adenocarcinoma - diffuse type, arising in gastric cardia type mucosa at gastro-oesophageal junction and extending through muscularis propria to the posterior serosal surface; metastatic tumour in three of six lymph nodes, two with extra nodal spread; proximal and distal mucosal resection margins clear of tumour.

2. "High paraoesophageal lymph node": Metastatic tumour identified.

3. "Low paraoesophageal lymph node": Metastatic tumour identified.

Pathologist:

Registrar:

Please contact the authorising Pathologist if you wish to discuss this case.

For enquiries on this report please contact
AUTHORISED BY

This is a COPY

FINAL - File Permanently

Printed:
Page 2 of 2

Source: NCI Genomic Data Commons file 9a8a059b-77d0-473e-ba79-4b11513edb6c (TCGA-RD-A7BS.1AB7B59A-511E-458C-A8C7-0D8C77DC47F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).